Somatic mutation profile of tumor specimen 0DEYGK from CCDI case PBBRKP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.8 years (1,770 days).
Specimen 0DEYGK: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b20b600e-04b2-402f-9f3c-6316c87fa84c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV2G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fafc8633-4dff-4301-b5be-c50f1ec0266a

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 4, 3'UTR 1, 3'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/328 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- L1TD1 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 149/530 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1028292503; called by muse, mutect2, varscan2
- L1TD1 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 160/566 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100776632; called by muse, varscan2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 18/425 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ATRX | c.4484del p.N1495Mfs*23 | Frame Shift Del (DEL) | VAF 64/90 reads (71%) | called by mutect2, varscan2
- C1QB | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.05); called by muse, mutect2
- CCR5 | c.525T>A p.H175Q | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- ERBIN | c.3583G>A p.D1195N | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FBP1 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MYCBPAP | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PAX4 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PDGFD | c.510G>T p.L170= | Splice Region (SNP) | VAF 24/145 reads (17%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TBX18 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TTBK1 | c.3065A>G p.D1022G | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1167537044; called by muse, mutect2, varscan2
- DLG4 | c.264C>T p.I88= (on ENST00000399506 / NM_001321075.3; = p.I131= on NM_001365.4) | Silent (SNP) | VAF 41/174 reads (24%) | catalogued as rs763705867; called by muse, mutect2, varscan2
- OR52A5 | c.384C>A p.I128= | Silent (SNP) | VAF 56/320 reads (18%) | catalogued as COSV56614692, COSV56614934; called by muse, mutect2, varscan2
- OR5D18 | c.369C>A p.R123= | Silent (SNP) | VAF 106/190 reads (56%) | catalogued as rs975731783; called by muse, varscan2
- PSPH | c.198A>G p.L66= | Silent (SNP) | VAF 41/304 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.80490C>T p.S26830= (on ENST00000591111; = p.S19406= on NM_003319.4) | Silent (SNP) | VAF 24/236 reads (10%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 11/79 reads (14%) | called by muse, varscan2
- DPEP1 | c.591+17C>T | Intron (SNP) | VAF 41/192 reads (21%) | catalogued as rs758208051; called by muse, mutect2, varscan2
- GFM1 | c.689+31T>A | Intron (SNP) | VAF 16/126 reads (13%) | catalogued as rs184145523; called by muse, varscan2
- MUC2 | chr11:1096960 C>G | 3'Flank (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2, varscan2
- SEC23A | c.279+51C>T | Intron (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- ZAN | c.*46T>A | 3'UTR (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
